Surgical pathology report (de-identified scan), TCGA case TCGA-L7-A6VZ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Christiana Care, specimen TCGA-L7-A6VZ-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

ICD-O-3

Adenocarcinoma NOS
8140/3

Site: Middle third esophagus
C15.4

path
Esophagus NOS
C15.9

7/25/13

Procedure:

Diagnosis

- A. Esophagus and proximal stomach, resection: Adenocarcinoma, moderately differentiated, into and focally through the muscularis propria (pT3); negative margins of resection; fourteen of nineteen lymph nodes with metastatic carcinoma (14/19).
- B. Lymph node, level 8, biopsy: One lymph node with metastatic carcinoma (1/1).

Microscopic Description:

Histologic type: Adenocarcinoma

Histologic grade: Moderately-differentiated

Primary tumor (pT3): Carcinoma into and focally through muscularis propria

Proximal/distal/radial margins: Negative (closest margin is proximal, 5 mm)

Vascular invasion: Present

Regional lymph nodes (pN): Fifteen of twenty lymph nodes with metastatic carcinoma (15/20); largest metastatic focus is 1.9 cm.

Extracapsular extension of carcinoma is present.

Other findings: Barrett's esophagus. The main tumor mass is distal; however, additional satellite tumor nodules are present in the upper esophagus, extending to within 5 mm of the proximal margin. Gastric mucosa is otherwise unremarkable.

Comment: Desmin immunostaining performed on two tissue blocks to assess the degree of invasion by carcinoma. Focus of carcinoma extending through the muscularis propria confirmed by

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

Specimen

- A. Esophagus and stomach
- B. Level 8 lymph node

Clinical Information

Esophageal cancer

Gross Description

A. Received fresh labeled "esophagus and stomach" is a previously unopened 13 cm segment of esophagus with attached 12.0 x 5.0 x 2.5 cm portion of proximal stomach. The external soft tissue surface of the esophageal segment is scabrous tan-pink with multiple palpable soft lymph nodes measuring up to 2.1 cm. The proximal and distal margins are 4.8 and 23.5 cm in circumference respectively. On opening, there is a well-circumscribed, 6.0 x 5.8 cm nearly circumferential soft tan-white-red tumor mass which appears to arise at the gastroesophageal junction (note the junction is not visually apparent and may be constituted by a staple line, as multiple staples are recovered from the area). On sectioning, the lesion has an apparent maximal thickness of 1.5 cm. A portion of the tumor and a portion of normal mucosa are submitted for tissue procurement as requested. Multiple additional

[page 2 of 2]
soft white pink-red tumor nodules measuring up to 4 cm in greatest dimension extend from within 1 cm of the proximal margin (as measured in the fresh state) to within 1 cm of the primary lesion. The largest additional lesion has a maximal thickness of 0.9 cm. All of the lesions appear greater than 0.5 cm from the inked surface of the specimen. The gastric mucosa is tan-pink-red with normal rugal folds and the wall averages 0.5 cm.

Summary: 1 - proximal margin with closest lesion,, 2 - perpendicular sections distal margin, 3 through 8 - primary lesion to inked surface, 9 through 11 - smaller lesions, 12 -possible EGJ, 13 - random gastric, 14 through 17 lymph nodes from esophageal segment as follows: 14 - 5 lymph nodes, 15 - 6 lymph nodes, 16 through 18 - one bisected lymph node per cassette 19 and 20 - lymph nodes recovered from adipose tissue associated with gastric portion of specimen as follows: 19 - 4 lymph nodes, 20 - one bisected lymph node

B. Received in formalin labeled "level 8 lymph node" is a 1.5 x 1.5 x 0.9 cm rubbery tan-white tissue in keeping with lymph node. The specimen is sectioned and entirely submitted.

UICAA Discrepancy		☒
Case is (ch. 34):		☒
Case is (ch. 34):		☒

Source: NCI Genomic Data Commons file 469e1fa5-be1f-41c0-be43-ca3d829dfbb8 (TCGA-L7-A6VZ.5257144B-2F39-44CE-ADB4-18CD4AB0B5A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).